Gene-level copy-number profile of tumor specimen C3L-03400-02 (profiled together with C3L-03400-05) from CPTAC case C3L-03400, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 38.4 years (14,028 days).
Specimen C3L-03400-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 67d77ff1-9c2f-433a-82bc-0a866d638d49.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03400-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/e3a5646c-d5f0-4c80-ba9f-c8f2f09a7205

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 9,850; copy number 2: 47,693; copy number 3: 821; copy number 4: 27; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,071,824–29,182,445, 9 genes (within-gene range 0–2): OR2P1P, SAR1AP1, OR2B3, OR2J1, OR2J3, AL645937.2, AL645937.1, OR2J2, OR2J4P.
- chr10:48,064,308–48,119,455, 1 gene: PTPN20CP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:48,040,462–48,060,016, 2 genes, copy number 6: RNA5SP315, BMS1P7.

Autosomal genes at a single copy (total copy number 1): 9,807. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
